Somatic mutation profile of tumor specimen TCGA-GV-A3QK-01B (aliquot TCGA-GV-A3QK-01B-11D-A23M-08) from TCGA case TCGA-GV-A3QK, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 57.0 years (20,802 days).
Specimen TCGA-GV-A3QK-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d085e56e-6818-458a-8187-58afa4101bf1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GV-A3QK-10A (Blood Derived Normal), aliquot TCGA-GV-A3QK-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81421f7e-7a0c-40bc-968a-fb10c326eb05

The open-access MAF lists 155 somatic variants for this specimen: 111 protein-altering or splice-affecting, 38 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 38, Nonsense Mutation 6, Frame Shift Del 5, Intron 3, Frame Shift Ins 2, RNA 2, In Frame Del 1, Splice Site 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN2 | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as rs200060005, CM1412995, COSV52489870, COSV52518440; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.1649T>C p.M550T | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs1355999421, COSV52212201; called by muse, mutect2, varscan2
- ABCC4 | c.2326G>A p.V776I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as rs146708960; called by muse, mutect2, varscan2
- ADAR | c.2450G>C p.R817T | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.452); catalogued as COSV52714284; called by muse, mutect2, varscan2
- ADGRL3 | c.2674T>C p.S892P (on ENST00000506720 / NM_001322402.2; = p.S824P on NM_015236.6) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs972360185, COSV72231949; called by muse, mutect2, varscan2
- AMPH | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.724); catalogued as COSV57748838, COSV57757059, COSV57757333; called by muse, mutect2, varscan2
- ANKRD55 | c.1101G>T p.R367S | Missense Mutation (SNP) | VAF 83/269 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.036); catalogued as COSV61944984, COSV61950718; called by muse, mutect2, varscan2
- ANKRD55 | c.1100G>T p.R367M | Missense Mutation (SNP) | VAF 80/266 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as COSV61950726; called by muse, mutect2, varscan2
- AP3D1 | c.3065C>T p.S1022F | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs938929196, COSV61432940; called by muse, mutect2, varscan2
- ARHGAP5 | c.1275G>C p.K425N | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV61539269; called by muse, mutect2, varscan2
- ARIH2 | c.571del p.R191Vfs*16 | Frame Shift Del (DEL) | VAF 132/313 reads (42%) | catalogued as COSV62703685; called by mutect2, pindel, varscan2
- ASB3 | c.1499A>G p.Y500C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs942042198, COSV55080134; called by muse, mutect2, varscan2
- ASCC2 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 106/439 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780074795, COSV57076665; called by muse, mutect2, varscan2
- ATOH1 | c.173G>T p.S58I | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV60038753; called by muse, mutect2, varscan2
- CD5 | c.1367C>A p.P456H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61719129; called by muse, mutect2, varscan2
- CHIT1 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as rs768872163, COSV55149904; called by muse, mutect2, varscan2
- CNKSR1 | c.2084C>G p.S695C (on ENST00000374253 / NM_001297647.2; = p.S688C on NM_006314.3) | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV58792972, COSV58794699; called by muse, mutect2, varscan2
- COIL | c.1543C>T p.L515F | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV53594065, COSV53594554, COSV53596635; called by muse, mutect2, varscan2
- COL11A1 | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.107); catalogued as COSV62187140, COSV62197346; called by muse, mutect2, varscan2
- CSNK2A1 | c.528G>A p.W176* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV53934760, COSV53935527; called by muse, mutect2, varscan2
- DCC | c.3442C>A p.L1148I | Missense Mutation (SNP) | VAF 74/101 reads (73%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as COSV71440631; called by muse, mutect2, varscan2
- DIDO1 | c.1052C>T p.T351I | Missense Mutation (SNP) | VAF 73/182 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs759817028, COSV56633888; called by muse, mutect2, varscan2
- DNAH11 | c.10621G>A p.E3541K | Missense Mutation (SNP) | VAF 42/67 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV60981225; called by muse, mutect2, varscan2
- DOCK5 | c.5501C>G p.S1834C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV52411427; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.893C>G p.S298C | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62570947; called by muse, mutect2, varscan2
- ERC2 | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 71/245 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.615); catalogued as COSV55663436; called by muse, mutect2, varscan2
- FAM78A | c.724A>C p.I242L | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV55993309; called by muse, mutect2, varscan2
- FAM9B | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs12839241, COSV59120385; called by muse, mutect2, varscan2
- FARSB | c.1693C>T p.H565Y | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56048034, COSV56052564; called by muse, mutect2, varscan2
- FGR | c.572G>C p.R191T | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV64969807; called by muse, mutect2, varscan2
- GNL2 | c.2136G>C p.K712N | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56171443; called by muse, mutect2, varscan2
- GOLGA4 | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62713812; called by muse, varscan2
- GPAT2 | c.1700G>A p.R567K | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV64004181; called by muse, mutect2, varscan2
- GRB10 | c.1559G>T p.R520L (on ENST00000398812; = p.R474L on NM_001001549.3) | Missense Mutation (SNP) | VAF 141/295 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60008156, COSV60016635; called by muse, mutect2, varscan2
- GRM2 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 57/275 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV56584098; called by muse, mutect2, varscan2
- GTF3C4 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.549); catalogued as COSV64646133; called by muse, mutect2, varscan2
- HERC1 | c.12476G>A p.G4159E | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71250256; called by muse, mutect2, varscan2
- HLA-DMB | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs12176347, COSV66870773; called by muse, mutect2, varscan2
- ICAM3 | c.1075C>G p.Q359E | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV50330133; called by muse, mutect2, varscan2
- IL2RB | c.1312C>G p.P438A | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as COSV53428549; called by muse, mutect2, varscan2
- KCNB1 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV65570877; called by muse, mutect2, varscan2
- KIAA0232 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56929453; called by muse, mutect2, varscan2
- KRTAP19-2 | c.122C>A p.S41* | Nonsense Mutation (SNP) | VAF 82/221 reads (37%) | catalogued as COSV61854863; called by muse, mutect2, varscan2
- LAMA2 | c.7437G>C p.L2479F | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.783); catalogued as rs1353846096, COSV70345102, COSV70355030; called by muse, mutect2, varscan2
- LMLN | c.1183C>G p.Q395E | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV57605032; called by muse, mutect2, varscan2
- LRRFIP2 | c.1164G>T p.Q388H | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60870324; called by muse, mutect2, varscan2
- LRRIQ3 | c.1654G>T p.V552F | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV63049991; called by muse, mutect2, varscan2
- LRSAM1 | c.133C>G p.P45A | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55942659; called by muse, mutect2, varscan2
- MAGEC1 | c.48G>C p.Q16H | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as rs763808010, COSV53581631; called by muse, mutect2, varscan2
- MAGEC1 | c.2194C>T p.Q732* | Nonsense Mutation (SNP) | VAF 104/190 reads (55%) | catalogued as rs1415891843, COSV53578051; called by muse, mutect2, varscan2
- MAP4K3 | c.1715-1G>A p.X572_splice | Splice Site (SNP) | VAF 32/61 reads (52%) | catalogued as COSV55718665; called by muse, mutect2, varscan2
- MARCHF11 | c.1021A>G p.S341G | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV60134991; called by muse, mutect2, varscan2
- MEFV | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.761); catalogued as COSV54827508; called by muse, mutect2, varscan2
- MGLL | c.460G>C p.E154Q (on ENST00000398104 / NM_001003794.2; = p.E164Q on NM_007283.6) | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV54030150; called by muse, mutect2, varscan2
- MTMR1 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 56/87 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV64892980; called by muse, mutect2, varscan2
- MUC17 | c.6866C>T p.T2289M | Missense Mutation (SNP) | VAF 303/660 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); catalogued as rs766705643, COSV60289702; called by muse, mutect2, varscan2
- MYLK3 | c.2267G>A p.S756N | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV67366850; called by muse, varscan2
- MYOM2 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs773090655, COSV50703228; called by muse, mutect2, varscan2
- NBEA | c.2740G>T p.E914* | Nonsense Mutation (SNP) | VAF 37/113 reads (33%) | catalogued as COSV59781082; called by muse, mutect2, varscan2
- NFASC | c.265C>T p.R89W (on ENST00000339876 / NM_001378329.1; = p.R83W on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs922818448, COSV100362566, COSV58380022; called by muse, mutect2, varscan2
- NLRP2 | c.3061G>C p.D1021H | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs747325012, COSV54757261; called by muse, mutect2, varscan2
- NOP9 | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV51868127; called by muse, varscan2
- NSF | c.1957C>A p.Q653K | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV56576691; called by muse, mutect2, varscan2
- OLIG3 | c.236A>T p.Q79L | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.306); catalogued as COSV62989203; called by muse, mutect2, varscan2
- OR2F1 | c.719C>A p.T240K | Missense Mutation (SNP) | VAF 81/171 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs73464588, COSV67332095; called by muse, mutect2, varscan2
- PCDHGB1 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.405); catalogued as COSV54033237; called by muse, mutect2, varscan2
- PDP1 | c.343A>G p.N115D | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52603827; called by muse, mutect2, varscan2
- PIGU | c.1194G>A p.Q398= | Splice Region (SNP) | VAF 41/129 reads (32%) | catalogued as rs753870202, COSV54166441; called by muse, mutect2, varscan2
- PLEKHA7 | c.1823_1842del p.S608* | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | catalogued as COSV63051038; called by mutect2, pindel, varscan2
- PNISR | c.2110T>C p.F704L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV65080787; called by mutect2, varscan2
- POLR1F | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 209/424 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55999699; called by muse, mutect2, varscan2
- PPM1A | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57788592; called by muse, mutect2, varscan2
- PPP1R21 | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV54289438; called by muse, mutect2, varscan2
- PRSS35 | c.1039G>A p.G347S | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765201576, COSV63801216; called by muse, mutect2, varscan2
- REEP2 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs780596207, COSV54735912; called by muse, mutect2, varscan2
- RELN | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs375141725; called by muse, mutect2, varscan2
- RILP | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV53961325; called by muse, mutect2, varscan2
- RRP1B | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV61480524; called by muse, mutect2, varscan2
- RWDD2A | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.856); catalogued as COSV52282505, COSV52285993; called by muse, mutect2, varscan2
- SAFB | c.2641G>A p.G881R | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs778094826, COSV52653975; called by muse, mutect2, varscan2
- SELP | c.1787C>T p.S596F | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs1211884118, COSV55258557; called by muse, mutect2, varscan2
- SERPINB11 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.699); catalogued as COSV66957823; called by muse, mutect2, varscan2
- SHROOM3 | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.103); catalogued as rs772290620, COSV56039392; called by muse, mutect2, varscan2
- SLC5A5 | c.1146A>T p.K382N | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as COSV55835528; called by muse, mutect2, varscan2
- SLCO5A1 | c.2080C>T p.R694* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as rs755181191, COSV52658493; called by muse, mutect2, varscan2
- SRRM2 | c.8117C>T p.S2706L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.778); catalogued as rs1160915487, COSV51941915; called by muse, mutect2, varscan2
- ST6GAL1 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 45/190 reads (24%) | PolyPhen benign (0.014); catalogued as COSV51475094; called by muse, mutect2, varscan2
- STARD3 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.722); catalogued as rs1567857691, COSV60422994; called by muse, mutect2, varscan2
- THSD4 | c.1882G>C p.E628Q | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV55984514; called by muse, mutect2, varscan2
- TMX2 | c.231G>A p.M77I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV53556310; called by muse, mutect2, varscan2
- TNRC6A | c.4808C>G p.S1603C | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59370172; called by muse, mutect2, varscan2
- UNC13C | c.5284A>C p.M1762L | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV52923920; called by muse, mutect2, varscan2
- ZFP36L1 | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60546888, COSV60547214; called by muse, mutect2, varscan2
- ZFP37 | c.1610G>C p.R537T | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV65288668; called by muse, mutect2, varscan2
- ZFP37 | c.1160G>C p.R387T | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.18); catalogued as COSV65288678; called by muse, mutect2, varscan2
- ZFP37 | c.357G>C p.Q119H | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV65288700; called by muse, mutect2, varscan2
- ZNF423 | c.1856A>T p.E619V (on ENST00000563137 / NM_001379286.1; = p.E611V on NM_015069.4) | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV52204581; called by muse, mutect2, varscan2
- ZNF510 | c.1106G>A p.R369K | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV56299100; called by muse, mutect2, varscan2
- ZNF862 | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs906190541, COSV56226187; called by muse, mutect2, varscan2
- ZRANB3 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51515925; called by muse, mutect2, varscan2
- ARID1A | c.6698_6715del p.R2233_L2238del | In Frame Del (DEL) | VAF 23/140 reads (16%) | called by mutect2, pindel, varscan2
- FLT3 | c.1470dup p.V491Sfs*15 | Frame Shift Ins (INS) | VAF 51/173 reads (29%) | called by mutect2, pindel, varscan2
- FOXA1 | c.1227_1231del p.E410Afs*3 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel
- GAS2L2 | c.1238G>A p.R413K | Missense Mutation (SNP) | VAF 162/322 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- LGR4 | c.1092C>A p.C364* | Nonsense Mutation (SNP) | VAF 31/83 reads (37%) | called by muse, mutect2, varscan2
- MBD6 | c.2012del p.P671Lfs*4 | Frame Shift Del (DEL) | VAF 25/50 reads (50%) | called by mutect2, pindel, varscan2
- NEO1 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDH8 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- RPL13 | c.627G>T p.K209N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- ZFP36L2 | c.111dup p.T38Dfs*46 | Frame Shift Ins (INS) | VAF 19/34 reads (56%) | called by mutect2, varscan2
- ZNF223 | c.228del p.N77Ifs*10 | Frame Shift Del (DEL) | VAF 49/189 reads (26%) | called by mutect2, pindel, varscan2
- ADCY2 | c.954C>G p.L318= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV57900444; called by muse, varscan2
- ADGRB2 | c.2610G>A p.T870= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs140870509; called by muse, mutect2, varscan2
- ALMS1 | c.8052A>G p.V2684= | Silent (SNP) | VAF 190/328 reads (58%) | catalogued as COSV52521990; called by muse, mutect2, varscan2
- ATG7 | c.193T>C p.L65= | Silent (SNP) | VAF 54/221 reads (24%) | catalogued as COSV61615705; called by muse, mutect2, varscan2
- CELA2A | c.243C>T p.Y81= | Silent (SNP) | VAF 47/130 reads (36%) | catalogued as COSV62748051; called by muse, mutect2, varscan2
- DMBX1 | c.516C>A p.G172= | Silent (SNP) | VAF 41/168 reads (24%) | catalogued as COSV63602603; called by muse, mutect2, varscan2
- DPP6 | c.1071C>T p.H357= (on ENST00000377770 / NM_001364500.2; = p.H295= on NM_001936.5) | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as rs764350772, COSV59645061; called by muse, mutect2, varscan2
- FOXC1 | c.1638C>T p.F546= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs1327937746, COSV66516294; called by muse, mutect2, varscan2
- GTF2B | c.654C>T p.F218= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV65137657; called by muse, mutect2, varscan2
- HHIPL1 | c.288C>T p.D96= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as rs142575301; called by muse, mutect2, varscan2
- HSDL2 | c.384C>T p.G128= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as rs1398900854, COSV52717286; called by muse, mutect2, varscan2
- ITIH2 | c.1710G>A p.S570= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs537160383, COSV64435228; called by muse, mutect2, varscan2
- LDHD | c.144G>A p.A48= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs372903097, COSV55580267, COSV55582022; called by muse, mutect2
- LIPF | c.204G>A p.K68= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV53286330; called by muse, mutect2, varscan2
- LRRN1 | c.1326G>A p.T442= | Silent (SNP) | VAF 34/144 reads (24%) | catalogued as rs1455331112, COSV60013119; called by muse, mutect2, varscan2
- MAST3 | c.489G>A p.G163= | Silent (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- MMP8 | c.951T>C p.F317= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV52634299; called by muse, mutect2, varscan2
- MRPS16 | c.195C>T p.L65= | Silent (SNP) | VAF 50/162 reads (31%) | catalogued as rs779045459, COSV60286801, COSV60286893; called by muse, mutect2, varscan2
- MUC5B | c.9393G>A p.T3131= | Silent (SNP) | VAF 65/219 reads (30%) | catalogued as rs778855110, COSV71589943; called by muse, mutect2, varscan2
- MYLK3 | c.1401G>T p.P467= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as COSV67366857; called by muse, mutect2, varscan2
- PARD6A | c.105G>A p.S35= | Silent (SNP) | VAF 47/148 reads (32%) | catalogued as rs1444479510, COSV54670435, COSV99537658; called by muse, mutect2, varscan2
- PASK | c.2436G>A p.R812= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as COSV52160464; called by muse, mutect2, varscan2
- PDCD2L | c.234C>T p.F78= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV55824870; called by muse, mutect2, varscan2
- POLRMT | c.3225C>T p.G1075= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as rs554250745, COSV52118829; called by muse, mutect2
- PTCHD3 | c.1368C>T p.V456= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs771956313, COSV71257272; called by muse, mutect2, varscan2
- RB1CC1 | c.3738A>G p.L1246= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV50274595; called by muse, mutect2, varscan2
- RNASE3 | c.99G>T p.T33= | Silent (SNP) | VAF 50/163 reads (31%) | catalogued as COSV58959987; called by muse, mutect2, varscan2
- RPH3A | c.1512G>A p.L504= (on ENST00000389385 / NM_001143854.2; = p.L500= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 67/279 reads (24%) | catalogued as rs1452963310, COSV66992992; called by muse, mutect2, varscan2
- SLC5A3 | c.1125G>C p.L375= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV62970021, COSV62973497; called by muse, mutect2, varscan2
- SLC8B1 | c.1530G>A p.Q510= | Silent (SNP) | VAF 51/245 reads (21%) | catalogued as COSV52530568; called by muse, mutect2, varscan2
- SMARCD2 | c.1314C>T p.V438= | Silent (SNP) | VAF 47/181 reads (26%) | catalogued as COSV56741825; called by muse, mutect2, varscan2
- SYNE3 | c.2827C>T p.L943= | Silent (SNP) | VAF 49/126 reads (39%) | catalogued as COSV62082713; called by muse, mutect2, varscan2
- TGM2 | c.1701C>T p.L567= | Silent (SNP) | VAF 98/331 reads (30%) | catalogued as rs746163265, COSV63932445; called by muse, mutect2, varscan2
- TLN2 | c.7305C>G p.S2435= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV60895715; called by muse, mutect2, varscan2
- TSPAN6 | c.558G>A p.Q186= | Silent (SNP) | VAF 28/47 reads (60%) | catalogued as COSV100885835, COSV65957581; called by muse, mutect2, varscan2
- UCHL1 | c.340C>T p.L114= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs1420548378, COSV52653257; called by muse, mutect2, varscan2
- ZFP37 | c.552G>A p.L184= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV65288689; called by muse, mutect2, varscan2
- ZNF608 | c.2475A>G p.K825= | Silent (SNP) | VAF 87/268 reads (32%) | catalogued as COSV60441482; called by muse, mutect2, varscan2
- ANXA13 | c.15+1489G>A | Intron (SNP) | VAF 36/124 reads (29%) | catalogued as COSV51623926, COSV51626616; called by muse, mutect2, varscan2
- EI24P4 | n.1042A>G | RNA (SNP) | VAF 56/237 reads (24%) | called by muse, mutect2, varscan2
- MTHFD1L | c.2847+4705C>T | Intron (SNP) | VAF 7/21 reads (33%) | catalogued as COSV66227503; called by muse, mutect2, varscan2
- SNORD114-13 | n.37A>T | RNA (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 27/63 reads (43%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- TTN | c.10361-4289C>T | Intron (SNP) | VAF 23/55 reads (42%) | catalogued as COSV60347594; called by muse, mutect2, varscan2
